MMRF case MMRF_1037 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a6de5e50-19f4-4a18-969a-f2587271b4b0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.3 years (29,704 days); ISS stage: I; Days to last known disease status: 96 days; Days to last follow up: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 88 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 10.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.231 mg/dL; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 361 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 9.9 g/dL; Glucose 6.16 mmol/L.
- Day 96 (ECOG 2): M Protein 5.2 g/dL; Hemoglobin 7.32 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 318 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 1.9 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 9.35 mmol/L.

Other clinical attributes
- Day -13: Weight: 46 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1037_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1037_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
